TCGA case TCGA-JW-A5VG — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0bd52d75-5113-4ef1-bc75-509f59eaef2b

Demographics
Sex at birth: female; Race: american indian or alaska native; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 35 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 35.9 years (13,109 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IIA; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 26 days; Days to treatment end: 53 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 27 days; Days to treatment end: 55 days; Treatment dose: 6,150 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 57 days; Days to treatment end: 57 days; Treatment dose: 4,745 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, Low Dose; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 0 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Lymph Node(s) Paraaortic.
   Recorded as not given: adjuvant Radiation Therapy, NOS, postoperative.

Follow-up (3 entries)
- Day -8 (preoperative): Days to imaging: -8 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement.
- Day 439 (post adjuvant therapy): Disease response: Tumor Free; ECOG performance status: 0.
- Day 834 (post adjuvant therapy): Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Initial Diagnosis; Weight: 110 kg; Height: 158 cm; BMI: 44.1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JW-A5VG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-JW-A5VG-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-JW-A5VG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-JW-A5VG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 5; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 5; Tobacco smoking history indicator: 1; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); New tumor event diagnosis indicator: No.
- Diagnostic ct result outcomes: Ct scan preop results: Pelvic Nodes Present.
- Treatment, Radiation therapy info: Brachytherapy type: LDR; Radiation therapy xrt type: External beam radiation; Radiation therapy dose paraaortic nodes: 0.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 40 mg/m2; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 5.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 40mg/m2; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 5.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 834 days; disease-specific survival: no event (censored), 834 days; disease-free interval: no event (censored), 834 days; progression-free interval: no event (censored), 834 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JW-A5VG-01A-11D-A28A-01): tumor purity 0.78, ploidy 2.07, whole-genome doublings 0.
